Somatic mutation profile of cancer-model specimen HCM-CSHL-0820-C34-85B (3D Organoid, passage 4; aliquot HCM-CSHL-0820-C34-85B-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0820-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Non-small cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: GX; Age at diagnosis: 70.8 years (25,843 days).
Specimen HCM-CSHL-0820-C34-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36a1fd27-1a1a-4742-ae61-6eead71b0516.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0820-C34-10A (Blood Derived Normal), aliquot HCM-CSHL-0820-C34-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4d3a87c-f897-48fc-aff9-0c80f10bace0

The open-access MAF lists 333 somatic variants for this specimen: 246 protein-altering or splice-affecting, 80 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 80, Nonsense Mutation 18, Frame Shift Del 9, Intron 5, Splice Site 2, Splice Region 2, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 5510/5783 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 194/713 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by muse, mutect2, varscan2
- PHEX | c.2237G>T p.C746F | Missense Mutation (SNP) | VAF 43/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057517799, CM136309; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 279/279 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTBL2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 158/482 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs775736072, COSV101379317; called by muse, mutect2, varscan2
- ACVR2A | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as COSV54019853; called by muse, mutect2, varscan2
- ADARB1 | c.1729G>A p.V577M (on ENST00000360697 / NM_001346687.2; = p.V537M on NM_001112.4) | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as rs367731799; called by muse, mutect2, varscan2
- AGTPBP1 | c.3062G>A p.R1021Q (on ENST00000357081 / NM_001330701.2; = p.R981Q on NM_015239.2) | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.982); catalogued as rs1212529549, COSV61274268; called by muse, mutect2
- ANTXR2 | c.1440A>G p.I480M | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1461170229; called by muse, mutect2
- ARHGAP36 | c.-145G>A | Splice Region (SNP) | VAF 149/637 reads (23%) | catalogued as rs1024165725, COSV99357667; called by muse, mutect2, varscan2
- ASB12 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 202/594 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771781825; called by muse, mutect2, varscan2
- ASTN1 | c.179C>G p.S60W | Missense Mutation (SNP) | VAF 153/372 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99922539; called by muse, mutect2, varscan2
- ATXN2L | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57365857, COSV57371185; called by muse, mutect2, varscan2
- ATXN2L | c.1355C>G p.S452C | Missense Mutation (SNP) | VAF 139/351 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV57366597; called by muse, mutect2, varscan2
- CACNG8 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 479/747 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs750396252, COSV54415420, COSV99555140; called by muse, mutect2, varscan2
- CEACAM21 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 382/642 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV51814115; called by muse, mutect2, varscan2
- CELSR1 | c.6046G>A p.D2016N | Missense Mutation (SNP) | VAF 251/488 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.692); catalogued as rs558016566; called by muse, mutect2, varscan2
- CEP57 | c.1435C>A p.Q479K | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV100334563; called by muse, mutect2, varscan2
- CER1 | c.368A>T p.K123I | Missense Mutation (SNP) | VAF 168/514 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV66603164; called by muse, mutect2, varscan2
- CFAP65 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as COSV55391002; called by muse, mutect2, varscan2
- CIP2A | c.1681A>G p.T561A | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1182117918; called by muse, mutect2, varscan2
- CLEC16A | c.1462G>C p.A488P | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101278037, COSV68501052; called by muse, mutect2, varscan2
- CNTN2 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528954738, COSV59351082; called by muse, mutect2, varscan2
- COL21A1 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs375705630, COSV55155273; called by muse, mutect2, varscan2
- COL4A5 | c.3967C>T p.P1323S | Missense Mutation (SNP) | VAF 84/416 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1158113032, COSV100086723, COSV60362142; called by muse, mutect2, varscan2
- CPSF4 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 119/442 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1346941431; called by muse, mutect2, varscan2
- CRYZL1 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs149023691; called by muse, mutect2, varscan2
- CWH43 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56936183, COSV56936996; called by muse, mutect2, varscan2
- CYLC2 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 111/366 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66336385; called by muse, mutect2, varscan2
- CYP4A11 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 93/204 reads (46%) | catalogued as COSV100152076; called by muse, mutect2, varscan2
- DCUN1D1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV53044422; called by muse, mutect2, varscan2
- DNAH7 | c.696G>C p.E232D | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV56786035; called by muse, mutect2, varscan2
- DPYSL5 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 155/556 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV99982498; called by muse, mutect2, varscan2
- DSP | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 39/367 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs750800025; called by muse, mutect2, varscan2
- EFNB3 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 199/398 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs745976643; called by muse, mutect2, varscan2
- ERGIC3 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 123/528 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as COSV54140341; called by muse, mutect2, varscan2
- FAM24B | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs755332320; called by muse, mutect2, varscan2
- FASTKD5 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 130/581 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs750278791; called by muse, mutect2, varscan2
- FGF16 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as COSV71546203; called by muse, mutect2
- FHAD1 | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 143/318 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs115203564; called by muse, mutect2, varscan2
- FMN2 | c.3640G>A p.G1214S | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.8); catalogued as rs368876164, COSV100142277; called by muse, mutect2, varscan2
- FSBP | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 37/524 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52594876; called by muse, mutect2
- GK | c.1426G>A p.G476S (on ENST00000427190 / NM_001205019.2; = p.G470S on NM_000167.6) | Missense Mutation (SNP) | VAF 51/708 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs61742225; called by muse, mutect2
- GSS | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 88/486 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99036635; called by muse, mutect2, varscan2
- HCFC1 | c.5950G>A p.A1984T | Missense Mutation (SNP) | VAF 238/859 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60070190; called by muse, mutect2, varscan2
- HELB | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV56076067; called by muse, mutect2, varscan2
- HIGD1A | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 104/356 reads (29%) | catalogued as rs11555619; called by muse, mutect2, varscan2
- HK2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51880259; called by muse, mutect2, varscan2
- HKDC1 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758122815, COSV63575988; called by muse, mutect2, varscan2
- IGHMBP2 | c.1178G>A p.R393K | Missense Mutation (SNP) | VAF 174/584 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV99662023; called by muse, varscan2
- IL5RA | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 158/471 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.867); catalogued as rs369528757; called by muse, mutect2, varscan2
- INPP4A | c.2378G>A p.R793Q (on ENST00000074304 / NM_001134224.1; = p.R754Q on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/515 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1231375445, COSV50789712; called by muse, mutect2, varscan2
- KIF20B | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746958313; called by muse, mutect2, varscan2
- LEAP2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs771383357, COSV51527893; called by muse, mutect2, varscan2
- MACF1 | c.21151G>C p.D7051H (on ENST00000372915; = p.D5096H on NM_012090.5) | Missense Mutation (SNP) | VAF 153/343 reads (45%) | catalogued as COSV57122779, COSV57131259; called by muse, mutect2, varscan2
- MAN1C1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 132/294 reads (45%) | catalogued as COSV56044871; called by muse, mutect2, varscan2
- MED7 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 75/280 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV99644237; called by muse, mutect2, varscan2
- MFSD3 | c.206G>C p.W69S | Missense Mutation (SNP) | VAF 399/943 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs988558607; called by muse, mutect2, varscan2
- MID1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 68/716 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV58192756; called by muse, mutect2
- MIEF1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1477159815, COSV57479208; called by muse, mutect2, varscan2
- MMRN1 | c.741G>C p.Q247H | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99306804; called by muse, mutect2, varscan2
- MORC3 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 113/113 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs1233418653, COSV68203568; called by muse, mutect2, varscan2
- MSANTD2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 171/596 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as rs771979165; called by muse, mutect2, varscan2
- NAPRT | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 465/786 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs962870447, COSV99063644; called by muse, mutect2, varscan2
- NCOR2 | c.2957G>T p.R986L | Missense Mutation (SNP) | VAF 56/470 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.736); catalogued as COSV100656811, COSV100657262; called by mutect2, varscan2
- NLRP4 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 116/197 reads (59%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV56707850; called by muse, mutect2, varscan2
- NOL8 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 94/332 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV62634161; called by muse, mutect2, varscan2
- NOL8 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 128/387 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62634987; called by muse, mutect2, varscan2
- NUMA1 | c.4468del p.R1490Vfs*18 | Frame Shift Del (DEL) | VAF 276/537 reads (51%) | catalogued as COSV61191693; called by mutect2, pindel, varscan2
- OR13C9 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52241437; called by muse, mutect2, varscan2
- P2RX6 | c.1157C>G p.S386C | Missense Mutation (SNP) | VAF 43/510 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs769433710; called by muse, mutect2
- PCDH11X | c.2052G>T p.L684F | Missense Mutation (SNP) | VAF 98/501 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as COSV100011660; called by muse, mutect2, varscan2
- PCDHGA5 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV53920326, COSV53955956; called by muse, mutect2, varscan2
- PIK3CA | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 141/394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55963671; called by muse, mutect2, varscan2
- PIWIL1 | c.1329G>C p.L443F | Missense Mutation (SNP) | VAF 127/274 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV99806113; called by muse, mutect2, varscan2
- PP2D1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 251/370 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs1303583551; called by muse, mutect2, varscan2
- PTPRT | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 193/857 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs751886972, COSV61960389; called by muse, mutect2, varscan2
- PXDN | c.3367G>A p.G1123R | Missense Mutation (SNP) | VAF 74/770 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186843770, COSV53247671; called by muse, mutect2
- SASH1 | c.2167C>G p.R723G | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1158613922, COSV100821177; called by muse, mutect2, varscan2
- SERPINH1 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 203/609 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.651); catalogued as rs1258116556; called by muse, mutect2, varscan2
- SH3TC1 | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 102/644 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV55281376; called by muse, mutect2, varscan2
- SLC6A13 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 144/441 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV100569929, COSV58258392; called by muse, mutect2, varscan2
- SLIT1 | c.3944G>A p.R1315Q | Missense Mutation (SNP) | VAF 150/310 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs762205152, COSV56582053; called by muse, mutect2, varscan2
- SLITRK1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV100999975; called by muse, mutect2, varscan2
- SORBS2 | c.2482G>C p.D828H | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV53006944; called by muse, mutect2
- SULT1C4 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs143857621; called by muse, mutect2, varscan2
- TBC1D10B | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as COSV69505113; called by muse, mutect2, varscan2
- TEKT5 | c.963G>C p.E321D | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1477255299, COSV99296447; called by muse, varscan2
- THBD | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 198/940 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs140335769; called by muse, mutect2, varscan2
- THOC7 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1454490174, COSV99890105; called by muse, mutect2, varscan2
- TMEM131 | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 95/360 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51783124; called by muse, mutect2, varscan2
- TMEM204 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 171/386 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54153666; called by muse, mutect2, varscan2
- TNXB | c.7471G>A p.E2491K (on ENST00000647633; = p.E2244K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/567 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs377071098, COSV100926542; called by muse, mutect2, varscan2
- TRIM36 | c.1709C>T p.T570I | Missense Mutation (SNP) | VAF 131/445 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs745445693; called by muse, mutect2, varscan2
- TRIM65 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 78/567 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs371626754; called by muse, mutect2, varscan2
- TTLL7 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 161/318 reads (51%) | catalogued as rs764916974; called by muse, mutect2, varscan2
- UBASH3A | c.1636G>C p.A546P | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV52312079; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1006C>G p.H336D | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV54439636; called by muse, mutect2, varscan2
- USP51 | c.1411G>T p.G471W | Missense Mutation (SNP) | VAF 153/562 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101540632; called by muse, mutect2, varscan2
- VIT | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 127/454 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV64896594; called by muse, mutect2, varscan2
- XIRP2 | c.1960G>T p.E654* (on ENST00000628543; = p.E829* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 67/225 reads (30%) | catalogued as COSV99740518; called by muse, mutect2, varscan2
- YDJC | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 213/610 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.15); catalogued as rs1333412985, COSV53037109; called by muse, mutect2, varscan2
- ZBTB16 | c.2002C>A p.L668I | Missense Mutation (SNP) | VAF 94/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60093474; called by muse, mutect2, varscan2
- ZBTB8B | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 157/336 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1163358466; called by muse, mutect2, varscan2
- ZC3H11B | c.2221C>G p.P741A | Missense Mutation (SNP) | VAF 149/706 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.056); catalogued as rs1268912540; called by muse, mutect2, varscan2
- ZFHX3 | c.6640C>G p.P2214A | Missense Mutation (SNP) | VAF 143/345 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51715937; called by muse, mutect2, varscan2
- ZKSCAN7 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs1157802667; called by muse, mutect2, varscan2
- ZNF157 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 109/394 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1000954104, COSV65659394; called by muse, mutect2, varscan2
- ZNF726 | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 115/209 reads (55%) | catalogued as COSV58043716; called by muse, mutect2, varscan2
- ZNF740 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746656723; called by muse, mutect2, varscan2
- ZNF777 | c.1780C>A p.R594S | Missense Mutation (SNP) | VAF 301/664 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); catalogued as COSV56096957; called by mutect2, varscan2
- ACBD3 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ACSS3 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ADAM12 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 119/234 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- AGK | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- AKNAD1 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ALPK2 | c.1985G>A p.R662K | Missense Mutation (SNP) | VAF 131/235 reads (56%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANGPTL2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 315/680 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANKK1 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 162/558 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ARHGAP31 | c.552T>G p.I184M | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); called by mutect2, varscan2
- BOD1L1 | c.2198C>A p.T733N | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- C1QL1 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 155/675 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C1QL2 | c.584T>G p.F195C | Missense Mutation (SNP) | VAF 344/474 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C3 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.134); called by muse, mutect2
- CAPN14 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 272/394 reads (69%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CASZ1 | c.2062C>T p.H688Y | Missense Mutation (SNP) | VAF 185/347 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- CCDC60 | c.720_722delinsAA p.S240Rfs*15 | Frame Shift Del (DEL) | VAF 153/545 reads (28%) | called by pindel, varscan2*
- CCNT2 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- CDC25A | c.438T>G p.F146L | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDK7 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDKL5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 103/362 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CDON | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 155/510 reads (30%) | called by muse, mutect2, varscan2
- CNKSR1 | c.1198G>C p.E400Q (on ENST00000374253 / NM_001297647.2; = p.E393Q on NM_006314.3) | Missense Mutation (SNP) | VAF 259/567 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.60C>G p.F20L | Missense Mutation (SNP) | VAF 127/295 reads (43%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRIPT | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CSH1 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 136/691 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSNK1E | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CX3CL1 | c.1166del p.S389Ifs*40 | Frame Shift Del (DEL) | VAF 118/327 reads (36%) | called by mutect2, pindel, varscan2
- DCAF11 | c.907-1G>C p.X303_splice | Splice Site (SNP) | VAF 149/621 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | c.1781C>G p.S594* | Nonsense Mutation (SNP) | VAF 98/321 reads (31%) | called by muse, mutect2, varscan2
- DCSTAMP | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 228/552 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DHX16 | c.2156C>A p.A719D | Missense Mutation (SNP) | VAF 143/483 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOCK11 | c.3010G>T p.A1004S | Missense Mutation (SNP) | VAF 225/583 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DOCK7 | c.3766C>G p.L1256V (on ENST00000635253 / NM_001367561.1; = p.L1225V on NM_033407.3) | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DPAGT1 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 112/439 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EGF | c.3416G>A p.G1139E | Missense Mutation (SNP) | VAF 14/409 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); called by muse, mutect2
- EGFLAM | c.2550C>G p.N850K (on ENST00000354891 / NM_001205301.2; = p.N842K on NM_152403.4) | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ENPP7 | c.1087_1121del p.K363Gfs*9 | Frame Shift Del (DEL) | VAF 185/586 reads (32%) | called by mutect2, pindel, varscan2
- ERMP1 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 140/461 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EXTL1 | c.334C>G p.R112G | Missense Mutation (SNP) | VAF 160/341 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FAT3 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT16 | c.1501G>T p.V501F | Missense Mutation (SNP) | VAF 179/936 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GPR15 | c.615del p.F205Lfs*5 | Frame Shift Del (DEL) | VAF 90/358 reads (25%) | called by mutect2, pindel, varscan2
- GTDC1 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, varscan2
- H2AX | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 226/669 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- H3-3A | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 242/267 reads (91%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- HECA | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 89/348 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- HGH1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 506/880 reads (58%) | called by muse, mutect2, varscan2
- HIVEP1 | c.7075C>G p.Q2359E | Missense Mutation (SNP) | VAF 152/368 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- IGF2R | c.7240C>G p.L2414V | Missense Mutation (SNP) | VAF 178/520 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ILRUN | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 129/472 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- INTS8 | c.2591C>G p.S864C | Missense Mutation (SNP) | VAF 197/532 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IQCC | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 127/277 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- KIAA1217 | c.1018G>T p.V340F | Missense Mutation (SNP) | VAF 205/414 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KLHDC7A | c.1667C>G p.S556C | Missense Mutation (SNP) | VAF 218/432 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KMT2D | c.8842C>T p.P2948S | Missense Mutation (SNP) | VAF 152/480 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRT13 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- LELP1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- LIMK1 | c.45G>C p.M15I | Missense Mutation (SNP) | VAF 267/633 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMTK2 | c.2657C>G p.S886C | Missense Mutation (SNP) | VAF 132/465 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- LRP1B | c.6608C>T p.S2203F | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MAGEC3 | c.1619A>T p.D540V | Missense Mutation (SNP) | VAF 53/672 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.225); called by muse, mutect2
- MAPK11 | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 190/514 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MED12L | c.5649G>A p.M1883I | Missense Mutation (SNP) | VAF 147/518 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.708); called by muse, mutect2
- MLXIP | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- MRPL37 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 153/311 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MRTFA | c.2285C>G p.S762C | Missense Mutation (SNP) | VAF 190/422 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NAV3 | c.1564C>A p.P522T | Missense Mutation (SNP) | VAF 132/402 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NCOR2 | c.2471A>T p.K824M | Missense Mutation (SNP) | VAF 34/702 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); called by muse, mutect2
- NFIA | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 162/329 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NLGN4X | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 296/485 reads (61%) | called by muse, mutect2, varscan2
- NLRC4 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 34/558 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); called by muse, mutect2
- NOTCH1 | c.4632C>G p.H1544Q | Missense Mutation (SNP) | VAF 35/715 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); called by muse, mutect2
- NRXN3 | c.733A>T p.N245Y (on ENST00000557594 / NM_001272020.2; = p.N877Y on NM_004796.6) | Missense Mutation (SNP) | VAF 152/577 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- NXPE1 | c.788G>C p.R263T (on ENST00000424269; = p.R121T on NM_152315.5) | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR13D1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 113/362 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR2AE1 | c.160del p.Q54Sfs*18 | Frame Shift Del (DEL) | VAF 124/518 reads (24%) | called by mutect2, pindel, varscan2
- OR2Y1 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4E1 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 117/467 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- OR6Y1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR9K2 | c.628C>G p.Q210E (on ENST00000305377; = p.Q188E on NM_001005243.1) | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- OTOGL | c.463G>T p.D155Y (on ENST00000547103; = p.D146Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PCDHA4 | c.839C>A p.S280* | Nonsense Mutation (SNP) | VAF 65/212 reads (31%) | called by muse, mutect2, varscan2
- PCF11 | c.4150T>C p.W1384R | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDAP1 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- PDF | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 242/572 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PIGN | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 108/198 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG7 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- POGLUT1 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 106/329 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- POLR3A | c.3432G>T p.V1144= | Splice Region (SNP) | VAF 70/136 reads (51%) | called by muse, mutect2, varscan2
- POU3F3 | c.290G>A p.W97* | Nonsense Mutation (SNP) | VAF 118/453 reads (26%) | called by muse, varscan2
- PPEF1 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PPP1R1C | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.396); called by muse, varscan2
- PRDM12 | c.918C>A p.S306R | Missense Mutation (SNP) | VAF 195/876 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PRICKLE2 | c.2338G>C p.D780H (on ENST00000295902; = p.D724H on NM_198859.4) | Missense Mutation (SNP) | VAF 128/435 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- QRFP | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 100/836 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- RAI14 | c.2384C>A p.S795Y | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RAI2 | c.608G>A p.C203Y | Missense Mutation (SNP) | VAF 238/345 reads (69%) | SIFT tolerated (0.52); PolyPhen benign (0.097); called by muse, varscan2
- RBMX | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- RLF | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ROBO3 | c.3346C>G p.P1116A | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RTCB | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 185/394 reads (47%) | called by muse, mutect2, varscan2
- RYBP | c.27_29delinsTT p.A10* | Frame Shift Del (DEL) | VAF 110/407 reads (27%) | called by pindel, varscan2*
- SARM1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 259/769 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SCIN | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 134/194 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- SCN1A | c.3805C>G p.L1269V (on ENST00000303395 / NM_001202435.3; = p.L1258V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SI | c.4372C>A p.L1458I | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SIPA1 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 206/553 reads (37%) | called by muse, mutect2, varscan2
- SLC2A11 | c.144G>C p.E48D (on ENST00000345044 / NM_001024938.4; = p.E55D on NM_030807.5) | Missense Mutation (SNP) | VAF 172/415 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMIM39 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 116/325 reads (36%) | called by muse, mutect2, varscan2
- STK38 | c.1082G>A p.C361Y | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SUGCT | c.1242G>T p.E414D (on ENST00000335693 / NM_001193313.2; = p.E440D on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 250/535 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SUN1 | c.1197G>A p.M399I (on ENST00000405266 / NM_001367651.1; = p.M279I on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/457 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYCP1 | c.2208G>C p.K736N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TAB2 | c.2027T>G p.L676W | Missense Mutation (SNP) | VAF 56/567 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TANC2 | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 107/342 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TASOR | c.1333G>T p.E445* (on ENST00000355628 / NM_001365636.2; = p.E49* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 94/145 reads (65%) | called by muse, mutect2, varscan2
- TCF23 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 231/881 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TENT4A | c.131A>T p.N44I | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0.02); called by muse, mutect2
- TMEM132B | c.1970T>A p.I657N | Missense Mutation (SNP) | VAF 100/384 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TMEM259 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 39/868 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- TOGARAM1 | c.3274G>A p.D1092N | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TRAF3 | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 180/635 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.368); called by mutect2, varscan2
- TTC6 | c.2988G>T p.R996S | Missense Mutation (SNP) | VAF 78/339 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by mutect2, varscan2
- TTC9 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 290/949 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- UBASH3A | c.1380_1386del p.S461Lfs*65 | Frame Shift Del (DEL) | VAF 64/174 reads (37%) | called by mutect2, pindel, varscan2
- UGT2A1 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 113/348 reads (32%) | called by muse, mutect2, varscan2
- UTRN | c.9937G>C p.E3313Q | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- WBP2NL | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 132/291 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WDR75 | c.374-1G>C p.X125_splice | Splice Site (SNP) | VAF 77/222 reads (35%) | called by muse, mutect2, varscan2
- WWC2 | c.173del p.E58Gfs*28 | Frame Shift Del (DEL) | VAF 164/521 reads (31%) | called by mutect2, pindel, varscan2
- YY1 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 326/1214 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNF274 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 328/330 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF571 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 103/291 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF71 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 200/551 reads (36%) | called by muse, mutect2, varscan2
- ZNF777 | c.1772_1777del p.L591_H592del | In Frame Del (DEL) | VAF 311/708 reads (44%) | called by mutect2, pindel, varscan2
- ACE | c.3204C>T p.L1068= | Silent (SNP) | VAF 116/530 reads (22%) | catalogued as rs189373608; called by muse, varscan2
- ANO3 | c.297C>A p.L99= | Silent (SNP) | VAF 54/221 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.2760G>A p.E920= | Silent (SNP) | VAF 93/345 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.3345G>A p.Q1115= | Silent (SNP) | VAF 88/291 reads (30%) | called by muse, mutect2, varscan2
- ARL6IP5 | c.483G>A p.P161= | Silent (SNP) | VAF 91/308 reads (30%) | catalogued as rs749163611, COSV56235474; called by muse, mutect2, varscan2
- ASB16 | c.654G>A p.A218= | Silent (SNP) | VAF 179/826 reads (22%) | catalogued as rs1555563885; called by muse, mutect2, varscan2
- ASB2 | c.195C>T p.I65= | Silent (SNP) | VAF 159/812 reads (20%) | called by muse, mutect2, varscan2
- BOC | c.2412G>A p.V804= | Silent (SNP) | VAF 93/323 reads (29%) | catalogued as COSV56350543; called by muse, mutect2, varscan2
- C16orf46 | c.631C>T p.L211= | Silent (SNP) | VAF 49/424 reads (12%) | called by muse, mutect2, varscan2
- C4orf50 | c.897C>G p.L299= | Silent (SNP) | VAF 102/524 reads (19%) | called by muse, mutect2, varscan2
- CACNA1H | c.2130G>A p.P710= | Silent (SNP) | VAF 239/578 reads (41%) | catalogued as rs757174542, COSV61994762; called by muse, mutect2, varscan2
- CASD1 | c.117C>G p.A39= | Silent (SNP) | VAF 153/643 reads (24%) | called by muse, mutect2, varscan2
- CC2D2A | c.432C>A p.G144= | Silent (SNP) | VAF 42/153 reads (27%) | called by muse, mutect2, varscan2
- CCDC80 | c.1989C>T p.F663= | Silent (SNP) | VAF 137/447 reads (31%) | catalogued as rs759163642; called by muse, mutect2, varscan2
- CD8B | c.24C>T p.L8= | Silent (SNP) | VAF 219/702 reads (31%) | called by muse, mutect2, varscan2
- CDH8 | c.1179A>G p.S393= | Silent (SNP) | VAF 44/376 reads (12%) | called by muse, mutect2, varscan2
- CEP170 | c.3789G>A p.L1263= | Silent (SNP) | VAF 154/333 reads (46%) | called by muse, mutect2, varscan2
- COL6A3 | c.3330C>T p.A1110= | Silent (SNP) | VAF 29/597 reads (5%) | catalogued as rs111328076; called by muse, mutect2
- CRYBG3 | c.3028C>T p.L1010= | Silent (SNP) | VAF 82/227 reads (36%) | called by muse, mutect2, varscan2
- CSTF1 | c.897T>A p.T299= | Silent (SNP) | VAF 146/641 reads (23%) | called by muse, mutect2, varscan2
- DCLK2 | c.297C>T p.F99= | Silent (SNP) | VAF 120/557 reads (22%) | called by muse, mutect2, varscan2
- DDI1 | c.864G>A p.G288= | Silent (SNP) | VAF 162/496 reads (33%) | catalogued as rs369975321; called by muse, mutect2, varscan2
- DOCK8 | c.3957G>T p.L1319= | Silent (SNP) | VAF 56/466 reads (12%) | called by muse, mutect2, varscan2
- DOP1A | c.3210C>T p.L1070= | Silent (SNP) | VAF 83/283 reads (29%) | catalogued as COSV52708132; called by muse, mutect2, varscan2
- FAM199X | c.1041G>A p.K347= | Silent (SNP) | VAF 152/500 reads (30%) | catalogued as rs868960081; called by muse, mutect2, varscan2
- FAT4 | c.1596G>A p.V532= | Silent (SNP) | VAF 38/386 reads (10%) | called by muse, mutect2
- FN1 | c.768C>G p.L256= | Silent (SNP) | VAF 137/484 reads (28%) | called by muse, mutect2, varscan2
- GADD45GIP1 | c.72C>A p.G24= | Silent (SNP) | VAF 25/711 reads (4%) | called by muse, mutect2
- GCNA | c.918C>T p.D306= | Silent (SNP) | VAF 179/553 reads (32%) | catalogued as rs978721815, COSV65466740; called by muse, mutect2, varscan2
- H2AX | c.381G>A p.P127= | Silent (SNP) | VAF 129/446 reads (29%) | called by muse, mutect2, varscan2
- H2BC4 | c.138G>A p.L46= | Silent (SNP) | VAF 70/253 reads (28%) | catalogued as rs757815054, COSV58417398; called by muse, mutect2, varscan2
- HK3 | c.948T>A p.G316= | Silent (SNP) | VAF 170/499 reads (34%) | called by muse, mutect2, varscan2
- HOXC9 | c.165C>T p.F55= | Silent (SNP) | VAF 290/853 reads (34%) | catalogued as rs1407570013, COSV57716319; called by muse, mutect2, varscan2
- HTT | c.8133C>T p.F2711= | Silent (SNP) | VAF 94/261 reads (36%) | catalogued as rs1043052578; called by muse, varscan2
- IGKV1-16 | c.294C>T p.S98= | Silent (SNP) | VAF 40/650 reads (6%) | catalogued as rs571561594; called by muse, mutect2
- IGSF11 | c.354C>T p.Y118= (on ENST00000393775 / NM_001015887.3; = p.Y117= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 127/417 reads (30%) | catalogued as rs1421706666, COSV61179156; called by muse, varscan2
- ILDR2 | c.1611G>A p.A537= | Silent (SNP) | VAF 246/522 reads (47%) | called by muse, mutect2, varscan2
- IRAK3 | c.1284G>A p.T428= | Silent (SNP) | VAF 78/241 reads (32%) | catalogued as rs373101549; called by muse, mutect2, varscan2
- ITSN2 | c.4611G>A p.Q1537= | Silent (SNP) | VAF 150/517 reads (29%) | called by muse, mutect2, varscan2
- KIF20B | c.1956A>T p.R652= | Silent (SNP) | VAF 47/230 reads (20%) | called by muse, mutect2, varscan2
- KIF2B | c.246T>C p.A82= | Silent (SNP) | VAF 352/711 reads (50%) | called by muse, mutect2, varscan2
- KLHL22 | c.150C>T p.F50= | Silent (SNP) | VAF 193/462 reads (42%) | catalogued as rs750344367, COSV100186128; called by muse, mutect2, varscan2
- LAMB2 | c.1491G>A p.V497= | Silent (SNP) | VAF 195/309 reads (63%) | called by muse, mutect2, varscan2
- LIN54 | c.24G>T p.V8= | Silent (SNP) | VAF 34/297 reads (11%) | called by muse, mutect2, varscan2
- LRCH3 | c.1170G>A p.V390= | Silent (SNP) | VAF 112/409 reads (27%) | called by muse, mutect2, varscan2
- LRRC9 | c.2643G>A p.L881= | Silent (SNP) | VAF 134/441 reads (30%) | catalogued as COSV99580702; called by muse, mutect2, varscan2
- MALSU1 | c.282C>T p.I94= | Silent (SNP) | VAF 79/323 reads (24%) | catalogued as COSV99799948; called by muse, mutect2, varscan2
- MAS1 | c.369G>T p.L123= | Silent (SNP) | VAF 136/435 reads (31%) | called by muse, mutect2, varscan2
- MATN3 | c.690C>G p.L230= | Silent (SNP) | VAF 40/648 reads (6%) | catalogued as rs202118156; called by muse, mutect2
- MCM3 | c.1207C>T p.L403= (on ENST00000229854 / NM_001366374.2; = p.L393= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 83/293 reads (28%) | called by muse, mutect2, varscan2
- MROH9 | c.1260C>T p.F420= | Silent (SNP) | VAF 119/275 reads (43%) | called by muse, mutect2, varscan2
- NAV3 | c.1563T>A p.I521= | Silent (SNP) | VAF 133/401 reads (33%) | called by muse, mutect2, varscan2
- NCAN | c.2115C>T p.F705= | Silent (SNP) | VAF 266/430 reads (62%) | catalogued as COSV99387320; called by muse, mutect2, varscan2
- NFS1 | c.363C>A p.I121= | Silent (SNP) | VAF 121/546 reads (22%) | called by muse, mutect2, varscan2
- NRP1 | c.195G>A p.Q65= | Silent (SNP) | VAF 95/209 reads (45%) | catalogued as COSV55174368; called by muse, mutect2, varscan2
- OBSL1 | c.1902C>T p.V634= | Silent (SNP) | VAF 147/501 reads (29%) | catalogued as rs1178607823; called by muse, mutect2, varscan2
- OR6N1 | c.429G>A p.E143= | Silent (SNP) | VAF 136/291 reads (47%) | catalogued as COSV58650110; called by muse, mutect2, varscan2
- OR9G4 | c.720C>T p.T240= | Silent (SNP) | VAF 140/477 reads (29%) | catalogued as rs1363489660; called by muse, mutect2, varscan2
- PDGFRA | c.1575C>G p.L525= | Silent (SNP) | VAF 44/428 reads (10%) | called by muse, mutect2
- PEX5L | c.1098C>A p.L366= | Silent (SNP) | VAF 115/394 reads (29%) | catalogued as COSV55856357; called by muse, mutect2, varscan2
- PIGV | c.735G>A p.V245= | Silent (SNP) | VAF 248/248 reads (100%) | catalogued as rs762221948, COSV50290874; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIK3AP1 | c.291C>T p.R97= | Silent (SNP) | VAF 173/363 reads (48%) | catalogued as rs752396501; called by muse, mutect2, varscan2
- PKD1L1 | c.5898C>T p.V1966= | Silent (SNP) | VAF 134/559 reads (24%) | called by muse, mutect2, varscan2
- PKD1L1 | c.4800G>A p.Q1600= | Silent (SNP) | VAF 112/443 reads (25%) | catalogued as COSV99218938; called by muse, mutect2, varscan2
- PNMA6A | c.567G>A p.S189= | Silent (SNP) | VAF 126/926 reads (14%) | catalogued as rs1276807373; called by muse, mutect2, varscan2
- PRAMEF6 | c.1353C>A p.I451= | Silent (SNP) | VAF 126/640 reads (20%) | catalogued as rs1210677374; called by muse, mutect2
- PRIMA1 | c.87C>T p.F29= | Silent (SNP) | VAF 277/937 reads (30%) | called by muse, mutect2, varscan2
- PRKG2 | c.1854T>A p.A618= | Silent (SNP) | VAF 49/422 reads (12%) | called by muse, mutect2, varscan2
- PTPN18 | c.171G>A p.V57= | Silent (SNP) | VAF 167/528 reads (32%) | catalogued as rs1234885311, COSV51558845; called by muse, mutect2, varscan2
- QRFPR | c.162C>G p.L54= | Silent (SNP) | VAF 242/786 reads (31%) | called by muse, mutect2
- RANBP1 | c.318G>A p.P106= | Silent (SNP) | VAF 16/292 reads (5%) | catalogued as rs564015023; called by muse, mutect2
- SLC38A10 | c.474C>A p.L158= | Silent (SNP) | VAF 142/608 reads (23%) | called by muse, mutect2, varscan2
- SLC38A8 | c.168C>T p.V56= | Silent (SNP) | VAF 126/271 reads (46%) | catalogued as rs747357201, COSV55306745; called by muse, mutect2, varscan2
- TRIM25 | c.1323G>A p.L441= | Silent (SNP) | VAF 213/474 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.78879C>T p.F26293= (on ENST00000591111; = p.F18869= on NM_003319.4) | Silent (SNP) | VAF 79/248 reads (32%) | called by muse, mutect2, varscan2
- TTYH1 | c.78C>T p.L26= | Silent (SNP) | VAF 170/516 reads (33%) | called by muse, mutect2, varscan2
- UCN2 | c.219C>A p.V73= | Silent (SNP) | VAF 211/675 reads (31%) | called by muse, mutect2, varscan2
- USP43 | c.1644C>T p.F548= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as COSV53299721; called by muse, mutect2, varscan2
- WDR7 | c.513A>T p.R171= | Silent (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- WWC3 | c.1995G>A p.P665= | Silent (SNP) | VAF 214/660 reads (32%) | catalogued as rs200232129; called by muse, varscan2
- DEUP1 | c.30-3026G>C | Intron (SNP) | VAF 138/346 reads (40%) | called by muse, mutect2, varscan2
- FRMD3 | c.1196-18512C>T | Intron (SNP) | VAF 92/266 reads (35%) | called by muse, mutect2, varscan2
- GPM6B | chrX:13772925 C>T | 3'Flank (SNP) | VAF 94/491 reads (19%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-28348C>A | Intron (SNP) | VAF 62/314 reads (20%) | called by mutect2, varscan2
- NPAP1L | n.575C>T | RNA (SNP) | VAF 33/235 reads (14%) | catalogued as rs1404087580; called by muse, mutect2, varscan2
- SCGB2A2 | c.243+59C>G | Intron (SNP) | VAF 127/414 reads (31%) | called by muse, mutect2, varscan2
- UHRF1 | c.-10-1376C>G | Intron (SNP) | VAF 155/448 reads (35%) | called by muse, mutect2, varscan2
